Somatic mutation profile of tumor specimen TCGA-AB-2814-03D (aliquot TCGA-AB-2814-03D-01W-0755-09) from TCGA case TCGA-AB-2814, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.5 years (14,427 days).
Specimen TCGA-AB-2814-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce02e6e1-ccf4-4caf-b0c5-548a6c649263.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2814-11B (Solid Tissue Normal), aliquot TCGA-AB-2814-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50be6d57-898f-41fa-b5f6-1312754d6b93

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2505T>G p.D835E | Missense Mutation (SNP) | VAF 33/92 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs121913487, COSV54044297, COSV54045054; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP11B | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs200423302, COSV100017616; called by muse, mutect2, varscan2
- CACNA1B | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs754545679, COSV53119020; called by muse, mutect2, varscan2
- HSD3B1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.143); catalogued as rs761714506, COSV99347841; called by muse, mutect2, varscan2
- PDE11A | c.2103C>A p.C701* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | catalogued as COSV99611229; called by muse, mutect2
- UPF1 | c.992T>A p.V331D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99439025; called by muse, mutect2, varscan2
- BCORL1 | c.1789dup p.T597Nfs*6 | Frame Shift Ins (INS) | VAF 50/140 reads (36%) | called by mutect2, pindel, varscan2
- ECPAS | c.2103A>C p.E701D | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2
- SHROOM2 | c.501C>A p.R167= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as COSV101098303; called by muse, mutect2, varscan2
- TMPRSS15 | c.2433C>T p.G811= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs377055842; called by mutect2, varscan2
